Somatic mutation profile of tumor specimen MMRF_2386_1_BM_CD138pos (aliquot MMRF_2386_1_BM_CD138pos_T1_KHS5U_L11233) from MMRF case MMRF_2386, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.8 years (23,680 days).
Specimen MMRF_2386_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31f26cd2-42ed-4516-81be-75221237fda9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2386_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2386_1_PB_Whole_C2_KHS5U_L11234; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0492dbe7-76e0-4ef1-98dd-6ca6f9fccf9c

The open-access MAF lists 98 somatic variants for this specimen: 39 protein-altering or splice-affecting, 12 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, 3'UTR 30, Silent 12, Intron 9, 3'Flank 3, Nonsense Mutation 3, 5'UTR 2, RNA 2, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACCS | c.810G>C p.Q270H | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.726); catalogued as COSV55460638; called by muse, mutect2
- CSMD3 | c.5294G>A p.R1765H (on ENST00000297405 / NM_001363185.1; = p.R1661H on NM_052900.3) | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.052); catalogued as rs762865438, COSV52165347, COSV99844662; called by muse, mutect2, varscan2
- DNMBP | c.1841G>A p.R614H | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147462477; called by muse, mutect2, varscan2
- EPHB2 | c.1310C>T p.S437L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); catalogued as rs1022230918; called by muse, mutect2, varscan2
- EPHB6 | c.1702G>A p.G568S | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as rs1295382569, COSV63892797, COSV63893087; called by muse, mutect2, varscan2
- H2AC21 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 75/227 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV58612454; called by muse, mutect2, varscan2
- H2BW1 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV54220784; called by muse, mutect2, varscan2
- IGHV3-53 | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.155); catalogued as rs1177826860; called by muse, varscan2
- IRGC | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 9/191 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1162537052; called by muse, mutect2
- LARS1 | c.3358G>A p.D1120N (on ENST00000394434 / NM_020117.11; = p.D1093N on NM_016460.3) | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.609); catalogued as COSV99198438; called by muse, mutect2, varscan2
- PCDH15 | c.4702G>T p.E1568* | Nonsense Mutation (SNP) | VAF 24/151 reads (16%) | catalogued as COSV57265818, COSV57295008; called by muse, mutect2, varscan2
- TNR | c.546del p.F183Lfs*82 | Frame Shift Del (DEL) | VAF 16/139 reads (12%) | catalogued as COSV54872154; called by mutect2, pindel, varscan2
- TTC26 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 55/216 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748726653, COSV58269432; called by muse, mutect2, varscan2
- ZNF491 | c.1125G>T p.R375S | Missense Mutation (SNP) | VAF 56/109 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as rs778522778; called by muse, mutect2, varscan2
- ADCY1 | c.1263T>A p.N421K | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- ALDOB | c.680C>G p.T227S | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- CCSER1 | c.2249A>G p.N750S | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP2F1 | c.880A>G p.N294D | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT tolerated (0.95); PolyPhen benign (0.028); called by muse, mutect2
- EPHB2 | c.1451C>G p.T484R | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAM83H | c.659C>T p.T220I | Missense Mutation (SNP) | VAF 79/181 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HOXD3 | c.633G>T p.K211N | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGHV3-53 | c.338A>T p.Y113F | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- IGKV4-1 | c.82C>G p.P28A | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by mutect2, varscan2
- MAML2 | c.3402G>C p.K1134N | Missense Mutation (SNP) | VAF 40/401 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- MARCHF4 | c.260G>C p.W87S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- MYO18B | c.2185G>T p.G729C | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NID1 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.079); called by muse, mutect2
- OBSL1 | c.4436G>C p.G1479A | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.46); PolyPhen probably damaging (1); called by muse, mutect2
- PARP8 | c.1960A>T p.K654* | Nonsense Mutation (SNP) | VAF 4/57 reads (7%) | called by muse, mutect2
- RPL10 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SH3GL3 | c.240G>T p.Q80H | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- SLC12A4 | c.769A>T p.I257F | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- SLC5A9 | c.602C>A p.T201N | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLCO4C1 | c.2075C>A p.P692Q | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- SLITRK4 | c.520A>T p.I174F | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by mutect2, varscan2
- TRIP13 | c.1074G>T p.M358I | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- TRRAP | c.5500C>T p.Q1834* (on ENST00000359863 / NM_001244580.1; = p.Q1816* on NM_003496.3) | Nonsense Mutation (SNP) | VAF 62/130 reads (48%) | called by muse, varscan2
- USP54 | c.2078G>C p.R693T | Missense Mutation (SNP) | VAF 67/120 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- ZSCAN29 | c.2366C>T p.P789L | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ADAMTS10 | c.3012G>A p.P1004= | Silent (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2, varscan2
- DAPK1 | c.1464C>T p.H488= | Silent (SNP) | VAF 217/336 reads (65%) | catalogued as rs774913098, COSV100802952; called by muse, mutect2, varscan2
- ERV3-1 | c.1152T>C p.S384= | Silent (SNP) | VAF 41/146 reads (28%) | called by muse, mutect2, varscan2
- GIPC3 | c.1791T>C p.S597= | Silent (SNP) | VAF 142/426 reads (33%) | catalogued as rs1369669855; called by muse, mutect2, varscan2
- GUCY1A2 | c.2145A>T p.I715= | Silent (SNP) | VAF 15/131 reads (11%) | called by muse, mutect2, varscan2
- IGHD3-9 | c.7C>A p.R3= | Silent (SNP) | VAF 25/26 reads (96%) | called by muse, varscan2
- IGHV3-53 | c.288G>A p.T96= | Silent (SNP) | VAF 30/102 reads (29%) | catalogued as rs781959246; called by muse, varscan2
- KCNA4 | c.915T>A p.P305= | Silent (SNP) | VAF 27/130 reads (21%) | called by muse, mutect2, varscan2
- LFNG | c.192G>A p.R64= | Silent (SNP) | VAF 96/190 reads (51%) | catalogued as rs747930822; called by muse, varscan2
- MROH1 | c.591G>A p.L197= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs372586117; called by muse, mutect2, varscan2
- PCLO | c.13725T>C p.I4575= | Silent (SNP) | VAF 12/20 reads (60%) | called by muse, mutect2, varscan2
- RAB29 | c.318A>G p.L106= | Silent (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- ABCG4 | chr11:119161939 G>A | 3'Flank (SNP) | VAF 57/187 reads (30%) | catalogued as rs927653452, COSV100266761; called by muse, mutect2, varscan2
- ALDH3A2 | c.1107+71A>G | Intron (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2, varscan2
- AMER2 | chr13:25165382 A>G | 3'Flank (SNP) | VAF 35/90 reads (39%) | called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.*1943T>G | 3'UTR (SNP) | VAF 19/41 reads (46%) | called by muse, mutect2, varscan2
- CALM1 | c.*582G>A | 3'UTR (SNP) | VAF 51/92 reads (55%) | called by muse, mutect2, varscan2
- CD226 | c.-27-105C>T | Intron (SNP) | VAF 6/114 reads (5%) | called by muse, mutect2
- CHORDC1 | c.*99A>G | 3'UTR (SNP) | VAF 51/225 reads (23%) | called by muse, mutect2, varscan2
- CHST10 | c.*598G>T | 3'UTR (SNP) | VAF 58/163 reads (36%) | called by muse, mutect2, varscan2
- CTNNBIP1 | chr1:9850503 C>G | 3'Flank (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2, varscan2
- EIF2AK4 | c.1819-1185T>C | Intron (SNP) | VAF 11/36 reads (31%) | called by muse, mutect2, varscan2
- FAM53A | c.*151C>T | 3'UTR (SNP) | VAF 22/82 reads (27%) | called by muse, varscan2
- FLRT3 | c.*1697G>C | 3'UTR (SNP) | VAF 4/76 reads (5%) | called by muse, mutect2
- GP6 | c.*396G>A | 3'UTR (SNP) | VAF 25/408 reads (6%) | catalogued as rs968768625; called by muse, mutect2
- GPR26 | c.*5604C>T | 3'UTR (SNP) | VAF 15/79 reads (19%) | catalogued as rs1235120087; called by muse, mutect2, varscan2
- HES2 | c.*1782C>T | 3'UTR (SNP) | VAF 8/40 reads (20%) | catalogued as rs937109108; called by muse, mutect2, varscan2
- IGFBP5 | c.*2496C>G | 3'UTR (SNP) | VAF 79/153 reads (52%) | called by muse, mutect2, varscan2
- KDM7A | c.*4306G>A | 3'UTR (SNP) | VAF 44/136 reads (32%) | called by muse, mutect2, varscan2
- KLF13 | c.*871G>C | 3'UTR (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2, varscan2
- KLF7 | c.*3935A>T | 3'UTR (SNP) | VAF 20/56 reads (36%) | called by muse, mutect2, varscan2
- KRTAP1-5 | c.*374C>G | 3'UTR (SNP) | VAF 6/83 reads (7%) | called by muse, mutect2
- LINC00632 | n.72A>T | RNA (SNP) | VAF 32/33 reads (97%) | called by muse, mutect2, varscan2
- MAPT | c.*538del | 3'UTR (DEL) | VAF 5/21 reads (24%) | called by mutect2, pindel
- MASP2 | c.*21G>A | 3'UTR (SNP) | VAF 29/60 reads (48%) | called by muse, mutect2, varscan2
- MOGAT2 | c.*1542del | 3'UTR (DEL) | VAF 22/120 reads (18%) | called by mutect2, pindel, varscan2
- MS4A15 | c.405+365A>G | Intron (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- MYO5A | c.*733C>T | 3'UTR (SNP) | VAF 24/44 reads (55%) | called by muse, mutect2, varscan2
- NPNT | c.*2473G>A | 3'UTR (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2, varscan2
- OPRM1 | c.-370A>T | 5'UTR (SNP) | VAF 44/327 reads (13%) | called by muse, mutect2, varscan2
- PLIN4 | c.*788C>T | 3'UTR (SNP) | VAF 42/136 reads (31%) | catalogued as rs1449040167; called by muse, mutect2
- PLOD1 | c.580-309T>C | Intron (SNP) | VAF 24/128 reads (19%) | called by muse, mutect2, varscan2
- RFX3 | c.*1244A>T | 3'UTR (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.558+151A>G | Intron (SNP) | VAF 6/8 reads (75%) | called by muse, mutect2, varscan2
- SCP2 | c.1081+5698C>T | Intron (SNP) | VAF 97/236 reads (41%) | called by muse, mutect2, varscan2
- SH3GL2 | c.*1011G>A | 3'UTR (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
- SHOX | c.*821C>G | 3'UTR (SNP) | VAF 19/198 reads (10%) | called by muse, mutect2
- SMS | c.*292G>A | 3'UTR (SNP) | VAF 63/114 reads (55%) | called by muse, mutect2, varscan2
- SOX11 | c.*4147G>A | 3'UTR (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- SSPOP | n.15739C>G | RNA (SNP) | VAF 15/43 reads (35%) | catalogued as COSV65127409; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.*56A>C | 3'UTR (SNP) | VAF 196/626 reads (31%) | catalogued as rs7547889; called by muse, mutect2, varscan2
- TBX18 | c.*1532C>A | 3'UTR (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- TMPO | c.*2213A>G | 3'UTR (SNP) | VAF 16/59 reads (27%) | called by muse, mutect2, varscan2
- TNK2 | chr3:195911881 C>T | 5'Flank (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2, varscan2
- TOMM40L | c.*297C>G | 3'UTR (SNP) | VAF 26/61 reads (43%) | called by muse, mutect2, varscan2
- UBC | c.-4+301T>A | Intron (SNP) | VAF 86/270 reads (32%) | catalogued as rs1425768783; called by muse, mutect2, varscan2
- WIPF3 | c.1428+50G>A | Intron (SNP) | VAF 9/211 reads (4%) | called by muse, mutect2
- WWP2 | c.*875G>A | 3'UTR (SNP) | VAF 16/47 reads (34%) | catalogued as rs1426386774; called by muse, mutect2, varscan2
- ZNF563 | c.-28G>A | 5'UTR (SNP) | VAF 70/208 reads (34%) | called by muse, mutect2, varscan2
